Surgical pathology report (de-identified scan), TCGA case TCGA-LP-A7HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site ILSBIO, specimen TCGA-LP-A7HU-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report (For Collection of Cancerous Tissue)

ICD O-3
Adenocarcinoma, endocervical type
8384/3

Site C40F
Corrux C53-9
Endocervix C53-0

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

9/10/13

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☐ Male ☒ Female			11/7	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abnormal vaginal bleeding
Symptoms: Weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses		# of Pregnancies
	_____ years old		03
	Date of Last Menses		# of Live Births
_____ years old			02
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____			☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy x	Adenocarcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Cervical Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Hysterectomy			
Primary Tumor			
Organ	Detailed Location		Size
Cervix tumor	Endocervix	1 x 0.8 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes		# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location		Size
Surgical Staging			
T 2 N 0 M 0			Stage: II

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

Date: _____

Time: _____

Preserved by: _____

Date: _____

Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
2	2	2	2			2	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Cervix Tumor	1 x 0.8 x cm	Endocervix	1 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N0 M0 Stage: II			
Notes: lympho nodes 2 (negative 2)			

[page 5 of 5]
IRB APPROVED

Form Revised

Consolidated Pathology Diagnosis

ID#: _____

Histological Pattern					
Cell Distribution			Structural Pattern		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration	☒		Pallisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psammoma/Calcification		

Cellular Differentiation									
Squamous		Adenomatous		Sarcomatous		Lymphomatous			
+	-	+	-	+	-	+	-	+	-
☒		☒		☒		☒		☒	
☒		☒		☒		☒		☒	
☒		☒		☒		☒		☒	
☒		☒		☒		☒		☒	
☒		☒		☒		☒		☒	
☒		☒		☒		☒		☒	

Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor

Nuclear Atypia:				
	0	I	II	III
Aniso Nucleosis				☒
Hyperchromatism				☒
Nucleolar Prominent				☒
Multinucleated Giant Cell				☒
Mitotic Activity				☒

Nuclear Grade: ☒

D. 50% D. 60%

Final Pathology Report

Histological Diagnosis: Papillary Adenocarcinoma Grade: 3

Follicular type

Comments: N1, N2: Carcinoma in situ.
N3: chronic lymphadenitis, N2: Carcinoma metastatic to LN

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - FOR

Source: NCI Genomic Data Commons file d3e05612-70cb-42ca-a893-7a986eb87d67 (TCGA-LP-A7HU.73BE0D97-1598-42A4-905B-3E652FF7D295.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).